Somatic mutation profile of tumor specimen 0DLA1Y from CCDI case PBBYZH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.0 years (3,271 days).
Specimen 0DLA1Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bdad833-37df-496a-ba50-0eadb3ae5520.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLA0Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/895356e7-4683-4823-b584-b5a5d40c8db4

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.2419C>A p.Q807K | Missense Mutation (SNP) | VAF 116/655 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.171); catalogued as COSV99263229; called by muse, varscan2
- ARHGEF40 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 309/675 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs754976173; called by muse, varscan2
- CCN4 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 224/441 reads (51%) | catalogued as rs777518726; called by muse, varscan2
- CD74 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 244/555 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335527634, COSV99153751; called by muse, varscan2
- COL4A5 | c.3904C>A p.Q1302K | Missense Mutation (SNP) | VAF 188/1031 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.233); catalogued as CM003669; called by muse, varscan2
- CROCC2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 274/507 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1225929493; called by muse, varscan2
- PAN2 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 323/702 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1326734091; called by muse, varscan2
- PCDHB13 | c.2071G>T p.V691L | Missense Mutation (SNP) | VAF 136/261 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as rs1554288130, COSV53397016; called by muse, varscan2
- RASSF8 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 152/736 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs776398938, COSV51453001; called by muse, varscan2
- TNPO2 | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.066); catalogued as rs747717622, COSV100790343; called by muse, varscan2
- AR | c.1682T>G p.L561R | Missense Mutation (SNP) | VAF 500/1065 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MRRF | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 152/664 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRIM1 | c.1248A>T p.L416F | Missense Mutation (SNP) | VAF 323/686 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, varscan2
- ZCCHC18 | c.155T>A p.V52E | Missense Mutation (SNP) | VAF 199/774 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.082); called by muse, varscan2
- DLGAP4 | c.1122C>T p.G374= | Silent (SNP) | VAF 110/471 reads (23%) | called by muse, varscan2
- MBLAC1 | c.678G>A p.V226= | Silent (SNP) | VAF 130/322 reads (40%) | catalogued as rs1470814034; called by muse, varscan2
- MTLN | c.186C>T p.N62= | Silent (SNP) | VAF 349/688 reads (51%) | called by muse, varscan2
- MVK | c.975C>T p.R325= | Silent (SNP) | VAF 202/970 reads (21%) | catalogued as rs748947620; ClinVar: likely benign; called by muse, varscan2
- RTTN | c.2256G>A p.P752= | Silent (SNP) | VAF 215/1271 reads (17%) | catalogued as rs778505726; called by muse, varscan2
- SMAD9 | c.1116C>T p.T372= (on ENST00000379826 / NM_001127217.3; = p.T335= on NM_005905.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 343/692 reads (50%) | catalogued as rs1266417138, COSV100614572; called by muse, varscan2
- TEAD1 | c.1242C>T p.H414= | Silent (SNP) | VAF 380/970 reads (39%) | catalogued as rs776934406; called by muse, varscan2
- NAA20 | c.53+521G>T | Intron (SNP) | VAF 214/506 reads (42%) | called by muse, varscan2
